CPTAC case C3N-01903 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1d7a842b-b567-4d55-b6ee-e63299439671

Demographics
Sex at birth: male; Race: white; Year of birth: 1969; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Papillary renal cell carcinoma: ICD-O-3 morphology code: 8260/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 48.2 years (17,616 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1b; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G1; Residual disease: R0; Days to last known disease status: 1,840 days (5.0 years); Progression or recurrence: no; Days to last follow up: 1,840 days (5.0 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 7 cm; Lymph nodes tested: 0; Margin status: Uninvolved; Sarcomatoid present: No.

Follow-up (6 entries)
- Days to follow up: 325 days; Disease response: Tumor Free.
- Days to follow up: 689 days (1.9 years); Disease response: Tumor Free.
- Days to follow up: 1,053 days (2.9 years); Disease response: Tumor Free.
- Days to follow up: 1,354 days (3.7 years); Disease response: Complete Response.
- Days to follow up: 1,354 days (3.7 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 1,840.

Other clinical attributes
- Weight: 79 kg; Height: 173 cm; BMI: 26.4.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01903-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -46 days; Initial weight: 228 mg; Time between excision and freezing: 8 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01903-24: Section location: Upper pole; Percent tumor nuclei: 85; Percent necrosis: 0.
- Sample C3N-01903-08: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -46 days; Initial weight: 322 mg; Time between excision and freezing: 8 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-01903-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -42 days; Method of sample procurement: Blood Draw.
